Somatic mutation profile of tumor specimen MMRF_1621_2_BM_CD138pos (aliquot MMRF_1621_2_BM_CD138pos_T1_KBS5U_L05841) from MMRF case MMRF_1621, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.2 years (22,004 days).
Specimen MMRF_1621_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d14b1e2-0555-4d6f-a55b-a56065f915e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1621_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1621_1_PB_Whole_C1_KHS5U_K14072; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/449945bc-eaca-428c-8052-f870701994e9

The open-access MAF lists 10 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 5, Missense Mutation 3, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNB | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs1446446854; called by muse, mutect2
- GPR180 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- N4BP2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- TMEM74B | c.610C>T p.L204= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- CALN1 | c.*1112C>T | 3'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- CD226 | c.*72del | 3'UTR (DEL) | VAF 4/33 reads (12%) | catalogued as COSV54610954; called by pindel, varscan2
- IGSF10 | c.*1803C>A | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- IL17RD | c.*3473C>T | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- RCVRN | c.-68C>T | 5'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- STAT5B | c.*347G>A | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
